CCDI case PBCNMN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/9ef7269c-b795-47b5-bc81-6def41ccc82c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 10.3 years (3,754 days).

Biospecimens (3 samples)
- Sample 0DW8GJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW8GU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DW8HB: Tissue type: Tumor; Specimen type: Solid Tissue.
